Somatic mutation profile of tumor specimen MP2PRT-PASWZM-TMP1-A (aliquot MP2PRT-PASWZM-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWZM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,288 days).
Specimen MP2PRT-PASWZM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b974ada4-47b9-4672-b51a-8ef803e7c6b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWZM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWZM-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/695d1b68-1389-4176-b7ee-403e5d933e69

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD55 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 157/347 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as rs367810872; called by muse, mutect2, varscan2
- CES1 | c.429del p.L144* | Frame Shift Del (DEL) | VAF 130/874 reads (15%) | catalogued as rs746985512, COSV100828677; called by mutect2, varscan2
- DNAH6 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs567660645; called by muse, mutect2, varscan2
- FAM83G | c.1913C>A p.A638D | Missense Mutation (SNP) | VAF 111/642 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.296); catalogued as rs747982022; called by muse, mutect2, varscan2
- GAL3ST3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 231/699 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1276618363, COSV61748926; called by muse, mutect2, varscan2
- MUC12 | c.13336G>A p.V4446I (on ENST00000379442; = p.V4303I on NM_001164462.1) | Missense Mutation (SNP) | VAF 105/704 reads (15%) | SIFT tolerated (0.66); catalogued as rs536228269; called by muse, mutect2, varscan2
- MYH9 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 150/392 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs569649580, COSV53393946; called by muse, varscan2
- PIDD1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 109/640 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs201895214, COSV100758594; called by muse, mutect2, varscan2
- RXFP3 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 130/793 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV100347793, COSV57504424; called by muse, mutect2, varscan2
- AHNAK2 | c.13412C>A p.P4471Q | Missense Mutation (SNP) | VAF 151/783 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKDD1B | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 308/645 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHV4-59 | chr14:106627239 CCTCACTGTGTCTCTCG>TGGGGAGGGC | Missense Mutation (DEL) | VAF 172/305 reads (56%) | called by pindel, varscan2*
- ISL1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 160/534 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUSK | c.2602A>T p.S868C | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SPAG17 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 166/645 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ASTN1 | c.3810G>A p.R1270= | Silent (SNP) | VAF 86/368 reads (23%) | catalogued as COSV62500998; called by muse, mutect2, varscan2
- GAN | c.990A>T p.V330= | Silent (SNP) | VAF 49/330 reads (15%) | called by muse, mutect2, varscan2
- NID1 | c.2634C>T p.C878= | Silent (SNP) | VAF 93/941 reads (10%) | catalogued as COSV51614420; called by muse, mutect2
- SLC12A5 | c.3267C>T p.D1089= (on ENST00000454036 / NM_001134771.2; = p.D1066= on NM_020708.5) | Silent (SNP) | VAF 79/521 reads (15%) | called by muse, mutect2, varscan2
- ZNF76 | c.1656G>A p.A552= | Silent (SNP) | VAF 157/371 reads (42%) | catalogued as rs150293971; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37718C>T | Intron (SNP) | VAF 229/858 reads (27%) | catalogued as rs1290467634; called by muse, mutect2, varscan2
